Somatic mutation profile of tumor specimen TCGA-QR-A707-01A (aliquot TCGA-QR-A707-01A-11D-A35D-08) from TCGA case TCGA-QR-A707, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 43.4 years (15,870 days).
Specimen TCGA-QR-A707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7d213e3-cc01-4d4a-b5f7-9317f1939cf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A707-10A (Blood Derived Normal), aliquot TCGA-QR-A707-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2583ce3-07e8-4a77-8d54-9818ba7b8572

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLXNA3 | c.3274C>T p.R1092W | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs1557207521; called by muse, mutect2, varscan2
- CD180 | c.1046A>T p.H349L | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.793); called by muse, mutect2
- HIC2 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- LIPJ | c.812A>T p.H271L | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- LSAMP | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2
- NXF3 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2, varscan2
